Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6297, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6297-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. RIGHT COLON

DIAGNOSIS:

A. RIGHT COLON, RIGHT HEMICOLECTOMY:

- EXOPHYTIC CIRCUMFERENTIAL ULCERATED INVASIVE MODERATE TO POORLY DIFFERENTIATED ADENOCARCINOMA OF CECUM, PROXIMAL ASCENDING COLON WITH EXTENSION TO ILEOCECAL VALVE, WITH FULL MUSCLE WALL THICKNESS INVASION, EXTENSION TO SUB-SEROSAL FAT., METASTASIS TO SIX OF THIRTY-SIX (6/36) PERICOLIC LYMPH NODES (WITH PERINODAL FAT EXTENSION).
- SIZE OF TUMOR- 8 X 4 X 1 CM.
- TUBULOVILLOUS ADENOMA (1.2 X 1.1 CM).
- VERMIFORM APPENDIX - NEGATIVE FOR TUMOR.
- PROXIMAL, DISTAL AND RADIAL MARGINS OF RESECTION - NEGATIVE FOR TUMOR.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Right hemicolectomy
Tumor Site:	Cecum,proximal ascending coln
Tumor Configuration:	Exophytic (polypoid), Infiltrative, Ulcerating
Tumor Size:	8.0 x 4.0 x 1.0 cm
Histologic Type:	Adenocarcinoma
Histologic Grade:	G3
Extent of Invasion:	Subserosa
Margins:	Margins uninvolved by invasive carcinoma
Venous/Lymphatic Invasion:	Present
Perineural Invasion:	Present
Additional Pathologic Findings:	Adenoma
Extent of Resection:	R0
Lymph Nodes:	Positive (6/36)
Implants:	Absent
EGFR Expression:	Pending
Pathologic Stage:	pT3 N2 MX

ADDENDUM:

Additional report:

Results of immunostain:

EGFR (section with tumor,#A5) - negative immunoreactivity

SPECIMEN(S):

A. RIGHT COLON

GROSS DESCRIPTION:

A. RIGHT COLON TERMINAL ILEUM:

Received fresh labeled with the patient's name, unit number and "right colon terminal ileum" is a 28.5x8.5x4 cm. right hemicolectomy specimen. The ileum is 8 cm. long and 7 cm. in circumference, the colon is 20.5 cm. long, 8.5 cm. in circumference and the attached appendix is 5.8 cm. long and 0.9 cm. in diameter. The serosal surface of the specimen is tan, smooth and multiple firm lymph nodes are palpated throughout the adherent pericolonic fat at the cecum. The specimen when opened shows a circumferential exophytic centrally ulcerated tumor with raised indurated peripheral borders occupying proximal ascending colon,cecum, and extending to involved the ileocecal valve,measuring 8x4x1.0 cm.

[page 2 of 2]
Tumor 14.5 cm from distal, and 5.5 cm from proximal margin. Cut sections show tan white granular surface, and tumor seen infiltrating muscle wall and grossly appears to extend to subjacent subserosal fat. The rest of colonic mucosa shows a flattened appearance, with a small polyp along hepatic flexure measuring 1.2x1.1 cm. Dissection of the adherent pericolonic fat shows multiple lymph nodes, the largest measuring 2x1.1x0.9 cm. Appendix is grossly free of tumor. Multiple sections submitted as follows in 30 cassettes labeled A1-A17. Block summary:

A1: margin

A2: apex

A3, A4, A5, A6: tumor and random section from ileum to colon

A7, A8: tumor

A9-A11: tumor deep section

A12: polyp

A13: three lymph nodes ileum

A14: three lymph nodes ileum

A15 lymph nodes cecum colon

A16: lymph nodes cecum colon

A17: two lymph nodes distal colon

A19-21: lymph nodes distal colon

A22-25: lymph nodes cecum

A26-30: sections of tumor, A29 and A30 are random sections

Source: NCI Genomic Data Commons file 001fee13-0e0d-464d-8b18-5641d51c86db (TCGA-G4-6297.9CB65EE5-2B85-49A4-A1FA-FE0DA865D74E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).